Somatic mutation profile of tumor specimen TCGA-RW-A67W-01A (aliquot TCGA-RW-A67W-01A-11D-A35D-08) from TCGA case TCGA-RW-A67W, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, NOS; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 46.5 years (16,983 days).
Specimen TCGA-RW-A67W-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a30b1e3c-0053-4e8f-848e-95ff471319a4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RW-A67W-10A (Blood Derived Normal), aliquot TCGA-RW-A67W-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6c8f554-3448-4a2e-91b0-90d3eb278350

The open-access MAF lists 6 somatic variants for this specimen: 5 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 4, Frame Shift Ins 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPB41 | c.1505C>A p.A502E (on ENST00000343067 / NM_001166005.2; = p.A293E on NM_004437.4) | Missense Mutation (SNP) | VAF 17/98 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.592); catalogued as COSV58040206; called by muse, mutect2, varscan2
- ILDR1 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs779374433; called by muse, mutect2, varscan2
- RYR1 | c.3299G>A p.R1100H | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755973279, COSV62110112; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MMP15 | c.1562A>G p.N521S | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- NAE1 | c.279dup p.Q94Tfs*5 | Frame Shift Ins (INS) | VAF 6/50 reads (12%) | called by mutect2, pindel, varscan2
- ERG | c.174C>T p.V58= | Silent (SNP) | VAF 9/77 reads (12%) | catalogued as COSV55727476; called by muse, mutect2, varscan2
